MMRF case MMRF_1432 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ae7a8c0b-3157-4852-a8e5-302f1165882c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Dead; Days to death: 401 days (1.1 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.8 years (24,764 days); ISS stage: III; Days to last known disease status: 401 days (1.1 years); Days to last follow up: 401 days (1.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 48 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 408 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 337 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 89 days; Days to treatment end: 194 days.
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 337 days; Days to treatment end: 393 days (1.1 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 348 days; Days to treatment end: 393 days (1.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 401.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 440 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.31 mg/dL; Beta 2 Microglobulin 7.94 µg/mL; Lactate Dehydrogenase 4.78 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 7.3 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 9.96 mmol/L.
- Day 82 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Beta 2 Microglobulin 3.96 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 5.5 g/dL; Glucose 5.17 mmol/L.
- Day 194 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.95 mg/dL; Beta 2 Microglobulin 2.36 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 5.5 g/dL; Glucose 7.04 mmol/L.
- Day 278 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 24.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2 mmol/L; Albumin 33 g/L; Total Protein 5.5 g/dL; Glucose 4.79 mmol/L.
- Day 348 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 184 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Beta 2 Microglobulin 8.55 µg/mL; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.43 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 6.55 mmol/L.

Other clinical attributes
- Day 1: Weight: 118 kg; Height: 182 cm.

Biospecimens (3 samples)
- Sample MMRF_1432_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1432_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1432_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 278 days.
